Somatic mutation profile of tumor specimen MMRF_2752_1_BM_CD138pos (aliquot MMRF_2752_1_BM_CD138pos_T1_KHS5U_L15083) from MMRF case MMRF_2752, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.5 years (20,650 days).
Specimen MMRF_2752_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47589eb5-7981-44c9-ad2a-76bea9d6788b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2752_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2752_1_PB_WBC_C2_KHS5U_L15084; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f9f0fe9-2e8f-4933-b2e4-183a1059a268

The open-access MAF lists 88 somatic variants for this specimen: 38 protein-altering or splice-affecting, 7 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 23, Intron 11, Silent 7, RNA 3, 5'UTR 3, Nonsense Mutation 3, 3'Flank 2, Frame Shift Del 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 55/140 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AGMO | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs769378096, COSV61105387, COSV61106804; called by muse, mutect2, varscan2
- CCDC83 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 48/154 reads (31%) | catalogued as COSV99721393; called by muse, mutect2, varscan2
- CUX1 | c.4153G>A p.D1385N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1349024125; ClinVar: uncertain significance; called by muse, mutect2
- DHH | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 93/187 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57201917; called by muse, mutect2, varscan2
- GDF2 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs782796080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV2-70 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 66/121 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.433); catalogued as rs372630587; called by muse, varscan2
- IGHV2-70 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1381225694; called by muse, varscan2
- IGLV3-1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 83/112 reads (74%) | SIFT tolerated (0.31); PolyPhen benign (0.166); catalogued as rs573884769; called by muse, mutect2, varscan2
- IGLV5-45 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 114/310 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.189); catalogued as rs759600760; called by muse, varscan2
- IGLV7-46 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs779148758; called by muse, mutect2, varscan2
- MAGEL2 | c.1201G>A p.V401I | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); catalogued as rs1020460740, COSV58565896; called by muse, mutect2, varscan2
- MRPS30 | c.553G>T p.V185L | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV101539289; called by muse, mutect2, varscan2
- MSX2 | c.650C>A p.P217H | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV99497011; called by muse, mutect2, varscan2
- MYH7 | c.3460G>A p.G1154S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1211784451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR5AC2 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV62279211; called by muse, mutect2, varscan2
- PLXNA2 | c.664G>T p.V222F | Missense Mutation (SNP) | VAF 90/235 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1048690080; called by muse, mutect2, varscan2
- POMGNT1 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | PolyPhen probably damaging (0.973); catalogued as rs769180238, COSV100915571; called by muse, mutect2, varscan2
- ANKZF1 | c.1692-7C>A | Splice Region (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- BAZ2A | c.2875C>T p.R959C | Missense Mutation (SNP) | VAF 78/131 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BRD8 | c.3645A>C p.K1215N | Missense Mutation (SNP) | VAF 125/328 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); called by muse, mutect2
- C1orf158 | c.89A>T p.N30I | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EEF2 | c.575A>G p.Y192C | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EML4 | c.1971G>T p.W657C | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRAS1 | c.4342G>C p.E1448Q | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- HMCN2 | c.5947G>T p.V1983L | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- IGHV2-70D | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, varscan2
- IGLV4-60 | c.332A>C p.Y111S | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGLV5-45 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 112/306 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.271); called by muse, varscan2
- INTS6 | c.703T>G p.F235V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNT2 | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- LRRC1 | c.843G>T p.L281F | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC1 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- MDN1 | c.6863T>G p.L2288R | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PAX9 | c.420C>G p.Y140* | Nonsense Mutation (SNP) | VAF 105/366 reads (29%) | called by muse, mutect2, varscan2
- SETX | c.7027G>A p.G2343S | Missense Mutation (SNP) | VAF 70/135 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNJ2 | c.3763C>T p.Q1255* | Nonsense Mutation (SNP) | VAF 120/249 reads (48%) | called by muse, mutect2, varscan2
- TENT5C | c.286del p.H96Mfs*22 | Frame Shift Del (DEL) | VAF 46/165 reads (28%) | called by mutect2, pindel, varscan2
- COL4A4 | c.4101G>C p.G1367= | Silent (SNP) | VAF 69/187 reads (37%) | called by muse, mutect2, varscan2
- GAA | c.1110C>T p.G370= | Silent (SNP) | VAF 13/186 reads (7%) | catalogued as rs775172804; called by muse, mutect2
- IGLV7-46 | c.162C>T p.P54= | Silent (SNP) | VAF 56/110 reads (51%) | catalogued as rs374868928; called by muse, mutect2, varscan2
- MMRN1 | c.1926G>A p.L642= | Silent (SNP) | VAF 69/211 reads (33%) | called by muse, mutect2, varscan2
- MTIF2 | c.1893C>G p.T631= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs1266387299; called by muse, mutect2, varscan2
- OR2G3 | c.357C>T p.A119= | Silent (SNP) | VAF 101/268 reads (38%) | called by muse, mutect2, varscan2
- PCDH1 | c.117G>T p.L39= | Silent (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- ADAM23 | c.*133G>A | 3'UTR (SNP) | VAF 34/96 reads (35%) | catalogued as rs1002119412; called by muse, mutect2, varscan2
- ANKRD29 | c.*1996A>C | 3'UTR (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- BCAR1 | c.-107G>A | 5'UTR (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- BIRC8 | n.1725_1728delinsATAT | RNA (ONP) | VAF 34/83 reads (41%) | called by pindel, varscan2*
- CHRM3 | c.*5433A>C | 3'UTR (SNP) | VAF 39/95 reads (41%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56811770 G>T | 3'Flank (SNP) | VAF 7/38 reads (18%) | catalogued as rs1203470234; called by muse, mutect2
- CLCN3 | c.*1121G>C | 3'UTR (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2
- CROCC | c.*405A>C | 3'UTR (SNP) | VAF 88/244 reads (36%) | called by muse, mutect2, varscan2
- CXorf38 | c.*634A>G | 3'UTR (SNP) | VAF 41/48 reads (85%) | called by muse, mutect2, varscan2
- DPM2 | c.3+142C>T | Intron (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
- FLVCR2 | c.*994G>C | 3'UTR (SNP) | VAF 27/69 reads (39%) | called by muse, mutect2
- HNRNPDL | chr4:82429955 C>T | 5'Flank (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- HSPA7 | n.801A>G | RNA (SNP) | VAF 70/147 reads (48%) | called by muse, mutect2, varscan2
- ISY1 | c.*1221C>T | 3'UTR (SNP) | VAF 93/203 reads (46%) | catalogued as rs1388778418; called by muse, mutect2, varscan2
- KCNE4 | c.*827C>T | 3'UTR (SNP) | VAF 6/176 reads (3%) | catalogued as COSV56054920; called by muse, mutect2
- LTB | c.163-156A>C | Intron (SNP) | VAF 57/140 reads (41%) | called by muse, mutect2, varscan2
- MAT2B | c.259-28T>A | Intron (SNP) | VAF 54/110 reads (49%) | called by mutect2, varscan2
- MCOLN3 | c.1095+1162G>A | Intron (SNP) | VAF 26/74 reads (35%) | catalogued as COSV62015176; called by muse, mutect2, varscan2
- MEGF11 | c.394+54137C>T | Intron (SNP) | VAF 27/75 reads (36%) | catalogued as rs1267146560; called by muse, mutect2, varscan2
- MEOX2 | c.*555T>G | 3'UTR (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- MKRN9P | n.750G>A | RNA (SNP) | VAF 27/96 reads (28%) | catalogued as rs531548490; called by muse, mutect2, varscan2
- NOX4 | c.*419T>G | 3'UTR (SNP) | VAF 55/198 reads (28%) | called by muse, mutect2, varscan2
- NPNT | c.-154C>T | 5'UTR (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- OAS1 | c.1039-641G>T | Intron (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- OPRM1 | c.1164+2739T>C | Intron (SNP) | VAF 34/113 reads (30%) | catalogued as rs1038382602; called by muse, mutect2, varscan2
- PDLIM5 | c.*1877T>G | 3'UTR (SNP) | VAF 86/211 reads (41%) | called by muse, mutect2, varscan2
- PRTFDC1 | c.*1064A>T | 3'UTR (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- PSMB8 | c.408-14T>G | Intron (SNP) | VAF 19/71 reads (27%) | called by muse, mutect2, varscan2
- RASGRP2 | c.1296+12C>T | Intron (SNP) | VAF 109/230 reads (47%) | catalogued as rs369856177; called by muse, mutect2, varscan2
- RFX3 | c.*562G>A | 3'UTR (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- RNF152 | c.*7261T>A | 3'UTR (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
- RSPRY1 | c.*1435T>A | 3'UTR (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- RSRC1 | c.912+63G>T | Intron (SNP) | VAF 53/186 reads (28%) | called by muse, mutect2, varscan2
- SIDT2 | c.*287T>C | 3'UTR (SNP) | VAF 138/324 reads (43%) | called by muse, mutect2, varscan2
- SLC35A3 | c.*1643A>C | 3'UTR (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- SNX19 | c.-152T>G | 5'UTR (SNP) | VAF 53/113 reads (47%) | called by muse, mutect2, varscan2
- STX16 | c.*1423T>G | 3'UTR (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
- TJP2 | c.*210G>A | 3'UTR (SNP) | VAF 43/103 reads (42%) | called by muse, mutect2
- TMPRSS11A | chr4:67909844 C>A | 3'Flank (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- TREML4 | c.506+2308C>T | Intron (SNP) | VAF 39/95 reads (41%) | called by muse, varscan2
- VAMP1 | c.*1616G>A | 3'UTR (SNP) | VAF 114/291 reads (39%) | catalogued as rs1006213055; called by muse, mutect2, varscan2
- WIF1 | c.*169T>C | 3'UTR (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2, varscan2
- ZNF749 | c.*70G>A | 3'UTR (SNP) | VAF 69/193 reads (36%) | called by muse, mutect2, varscan2
